ALCHEMIST case ALCH-AD75 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/014e7757-e045-47ee-a857-dd40128fde50

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 54.4 years (19,876 days).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AD75-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AD75-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AD75-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 40; Percent neutrophil infiltration: 20.
- Sample ALCH-AD75-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AD75-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 48; Percent normal cells: 64; Percent necrosis: 4; Percent stromal cells: 12; Percent lymphocyte infiltration: 44; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
